Somatic mutation profile of tumor specimen ALCH-B27J-TTP1-A (aliquot ALCH-B27J-TTP1-A-3-0-D-A77J-36) from ALCHEMIST case ALCH-B27J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.8 years (25,509 days).
Specimen ALCH-B27J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cca5c67f-44fb-4367-8f1e-56e1f7a8aa7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27J-NB1-A (Blood Derived Normal), aliquot ALCH-B27J-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6dca935-1949-4b13-98ea-da3dacffd802

The open-access MAF lists 496 somatic variants for this specimen: 340 protein-altering or splice-affecting, 95 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 297, Silent 95, Intron 33, Nonsense Mutation 30, RNA 10, 3'UTR 8, Splice Site 5, 5'Flank 5, 5'UTR 4, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 109/192 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV61356906; called by muse, varscan2
- ADCY8 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV53917149; called by muse, mutect2, varscan2
- ADD2 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52454197; called by muse, mutect2, varscan2
- AGXT2 | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536786734; called by muse, mutect2, varscan2
- ANK1 | c.5630C>T p.S1877L | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs756188673; called by muse, mutect2
- ANKFN1 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568024401; called by muse, mutect2, varscan2
- AOX1 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV65979860; called by muse, mutect2
- ARID5B | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs569211514; called by muse, mutect2, varscan2
- ARSG | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs778128173, COSV71593687; called by muse, mutect2, varscan2
- ATG2A | c.5384C>T p.S1795F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs754076734; called by muse, mutect2, varscan2
- ATG2A | c.4738G>T p.V1580F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV65967030; called by muse, mutect2, varscan2
- B3GNT5 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as COSV58475677; called by muse, mutect2, varscan2
- BSX | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1018888705, COSV58006678; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.442); catalogued as rs1323160957, COSV68516564; called by muse, mutect2, varscan2
- CALCOCO1 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753144693; called by muse, mutect2, varscan2
- CARF | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745337606, COSV57547415; called by muse, mutect2, varscan2
- CCDC7 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs181757977, COSV56543821; called by muse, mutect2
- CDK13 | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV51702721; called by muse, mutect2, varscan2
- CEBPZ | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs766192436, COSV50016910; called by muse, mutect2, varscan2
- CELSR1 | c.7481G>A p.R2494H | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs1317741440; called by muse, mutect2, varscan2
- CIITA | c.2077G>T p.G693C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761411956; called by muse, mutect2, varscan2
- CLEC14A | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs767466452; called by muse, mutect2, varscan2
- COL16A1 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs763318427; called by muse, mutect2, varscan2
- CORO7 | c.1380G>C p.L460F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as COSV99226985; called by muse, mutect2, varscan2
- CR2 | c.2466G>C p.M822I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs568997285; called by muse, mutect2
- CRACD | c.3084G>T p.K1028N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as COSV99950112; called by muse, mutect2, varscan2
- CRTAC1 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV54000685, COSV99037833; called by muse, mutect2, varscan2
- CRYM | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV54832589; called by muse, mutect2, varscan2
- CSMD3 | c.8356G>C p.D2786H (on ENST00000297405 / NM_001363185.1; = p.D2617H on NM_052900.3) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs747333485, COSV52183071, COSV52285643; called by muse, mutect2, varscan2
- CSNK1D | c.1058-3C>T | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as rs369563163; called by muse, mutect2
- CUL7 | c.4142A>G p.Y1381C | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.733); catalogued as rs774156355; called by muse, mutect2, varscan2
- DOK2 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as rs373240046; called by muse, mutect2, varscan2
- DSPP | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.508); catalogued as rs777881699; called by muse, mutect2, varscan2
- DUT | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1210602567, COSV58664240, COSV58664529; called by muse, mutect2, varscan2
- DZIP3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV64311550; called by muse, mutect2, varscan2
- EFCAB8 | c.2036G>T p.S679I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1396298072; called by muse, mutect2, varscan2
- EIF5B | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1269530504; called by muse, mutect2
- ENO2 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.111); catalogued as rs147018165; called by muse, mutect2, varscan2
- EP300 | c.4879C>T p.R1627W | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54325405, COSV54343776; called by muse, mutect2, varscan2
- EXT1 | c.1817G>C p.W606S | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM970451; called by muse, mutect2, varscan2
- FABP4 | c.355G>C p.V119L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56268878; called by muse, mutect2
- FMR1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV54423863; called by muse, mutect2, varscan2
- FRYL | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as rs755502038; called by muse, mutect2, varscan2
- GALNT2 | c.1297G>C p.V433L | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV100795973; called by muse, mutect2, varscan2
- GLI1 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); catalogued as COSV57359711; called by muse, mutect2
- GTF2A1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV53337272; called by muse, mutect2, varscan2
- HEATR5B | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1330362641; called by muse, mutect2, varscan2
- HERC1 | c.5097G>C p.E1699D | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV71250810; called by muse, varscan2
- HEXIM1 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs746307675; called by muse, varscan2
- HSF5 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV60419477; called by muse, mutect2, varscan2
- IGHV1-45 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782767868; called by muse, mutect2
- KIAA1549 | c.3226C>T p.L1076F | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.047); catalogued as COSV54306583; called by muse, mutect2, varscan2
- LAMA5 | c.6772C>T p.R2258* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as rs1382493765; called by muse, mutect2, varscan2
- LYST | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1373705285; called by muse, mutect2, varscan2
- MADD | c.3926C>G p.S1309C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs757707108; called by muse, mutect2, varscan2
- MAP2 | c.5272G>A p.D1758N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1488604359; called by muse, mutect2
- MCM5 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as COSV53348161, COSV99332126; called by muse, mutect2, varscan2
- MDGA2 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158174718; called by muse, mutect2, varscan2
- MEIOC | c.2555T>C p.I852T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs1568136499; called by muse, mutect2, varscan2
- MROH2A | c.3750C>G p.I1250M | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1172714179; called by muse, mutect2, varscan2
- MST1R | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs772397266, COSV56566578; called by muse, mutect2, varscan2
- MYLK | c.5629G>A p.D1877N | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60614790; called by muse, mutect2, varscan2
- MYLK2 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs770678849; called by muse, mutect2, varscan2
- NAV3 | c.6890A>G p.Y2297C (on ENST00000397909 / NM_001024383.2; = p.Y2275C on NM_014903.6) | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs746817165; called by muse, mutect2, varscan2
- NGRN | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1345541278; called by muse, mutect2, varscan2
- NOTCH1 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs371333249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs758196970; called by muse, mutect2, varscan2
- NRXN2 | c.5057C>A p.A1686E | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV55463667; called by muse, mutect2, varscan2
- OR4D5 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV58308328; called by muse, mutect2
- OR51A7 | c.928T>C p.C310R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV63788925; called by muse, mutect2, varscan2
- OR52A5 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV56615045; called by muse, mutect2, varscan2
- PARD3B | c.2620G>T p.A874S (on ENST00000406610 / NM_001302769.2; = p.A805S on NM_057177.7) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.628); catalogued as COSV62506112; called by muse, mutect2, varscan2
- PBRM1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56275393; called by muse, mutect2, varscan2
- PCDHB3 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1344403723; called by muse, mutect2, varscan2
- PDE7A | c.1445C>G p.S482* (on ENST00000401827 / NM_001242318.3; = p.S456* on NM_002603.4) | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65152175; called by muse, mutect2
- PHF10 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59324824; called by muse, mutect2, varscan2
- PHF21B | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448839516, COSV57557066; called by muse, mutect2, varscan2
- PHF3 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as rs774322145, COSV50351738; called by muse, mutect2, varscan2
- PKD1L1 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1038231582; called by muse, mutect2, varscan2
- PKP2 | c.1359G>C p.E453D | Missense Mutation (SNP) | VAF 33/340 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV50752328; called by muse, mutect2
- POLG | c.3624G>C p.R1208S | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as COSV99174552; called by muse, mutect2, varscan2
- POMT2 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs745680157; called by muse, mutect2
- POU3F3 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.013); catalogued as COSV63721324; called by mutect2, varscan2
- PPP1R32 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58544671; called by muse, mutect2, varscan2
- PROS1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as CM163614, COSV62398286; called by muse, mutect2, varscan2
- PRPF31 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV58087691; called by muse, mutect2, varscan2
- PRPS1L1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.646); catalogued as rs751865681, COSV72649817; called by muse, mutect2, varscan2
- PSMD1 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs780697471; called by muse, mutect2, varscan2
- PTCH1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs144323077, COSV59491241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN12 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50361559; called by muse, mutect2, varscan2
- RAB40AL | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769493325; called by mutect2, varscan2
- RALGAPB | c.1838C>T p.S613F | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV53442131; called by muse, varscan2
- RFX7 | c.580C>T p.Q194* (on ENST00000559447 / NM_001368074.1; = p.Q291* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 89/325 reads (27%) | catalogued as rs377452165; called by muse, mutect2, varscan2
- SFMBT2 | c.796T>A p.S266T | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100738252; called by muse, mutect2, varscan2
- SIAE | c.1340A>G p.H447R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs147161431; called by muse, mutect2, varscan2
- SIGLEC12 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV52461919; called by muse, mutect2, varscan2
- SLC26A5 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV59700093; called by muse, mutect2, varscan2
- SLC4A10 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs1158699240; called by muse, mutect2, varscan2
- SMARCD1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67413320; called by muse, mutect2, varscan2
- SPHKAP | c.2471C>G p.S824* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV60871599; called by muse, mutect2, varscan2
- SPIRE2 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184015109; called by muse, mutect2, varscan2
- SRRM1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs776382421; called by muse, mutect2, varscan2
- STAM | c.1390A>G p.M464V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs782495202; called by muse, varscan2
- TAAR9 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); catalogued as COSV71512245; called by muse, mutect2, varscan2
- TBC1D12 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs777561181; called by muse, mutect2, varscan2
- TET2 | c.2629G>C p.D877H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV54415646; called by muse, mutect2, varscan2
- TNIP1 | c.1370C>G p.T457R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV59307840; called by muse, mutect2, varscan2
- TPI1 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.047); catalogued as rs782181569; called by muse, mutect2, varscan2
- TPK1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63648057, COSV63648765; called by muse, mutect2, varscan2
- TRPM3 | c.2439G>T p.E813D (on ENST00000357533 / NM_001366142.2; = p.E656D on NM_020952.6) | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100676866; called by muse, mutect2, varscan2
- TRPM4 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs371377895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 95/233 reads (41%) | catalogued as rs118203512, CM981934; ClinVar: not provided; called by muse, mutect2, varscan2
- TSHZ3 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53671157, COSV53677676; called by muse, mutect2, varscan2
- TTN | c.27856G>A p.E9286K (on ENST00000591111; = p.E8359K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | PolyPhen possibly damaging (0.894); catalogued as COSV60176556; called by muse, mutect2, varscan2
- TTN | c.16028T>C p.V5343A (on ENST00000591111; = p.V4416A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | PolyPhen possibly damaging (0.775); catalogued as COSV100592261, COSV100610617; called by muse, mutect2, varscan2
- UBR5 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as rs145670915; called by mutect2, varscan2
- USP29 | c.2640C>A p.F880L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54142545, COSV54144333; called by muse, mutect2, varscan2
- WDFY4 | c.5551G>C p.A1851P | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV99630789; called by muse, mutect2, varscan2
- WWP1 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99615367; called by muse, mutect2, varscan2
- ZFHX4 | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.359); catalogued as COSV51486037, COSV99264178; called by muse, mutect2, varscan2
- ZNF608 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378869388; called by muse, mutect2, varscan2
- ZNF736 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1218505554; called by muse, mutect2, varscan2
- ZNRF2 | c.566-1G>T p.X189_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100546221; called by muse, mutect2, varscan2
- ABCC9 | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2
- ABHD15 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AC126283.2 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.054); called by muse, mutect2
- ACACB | c.1942G>T p.V648F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM23 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS17 | c.1889-1G>A p.X630_splice | Splice Site (SNP) | VAF 27/103 reads (26%) | called by muse, varscan2
- ADGRG6 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- AIFM3 | c.1790T>C p.M597T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ALPK3 | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- ANGPTL3 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ANKRD36C | c.5136G>C p.Q1712H | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ANKRD62 | c.2394C>A p.D798E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.078); called by mutect2, varscan2
- AP5Z1 | c.1836T>A p.C612* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP9 | c.1841-1G>A p.X614_splice (on ENST00000393797 / NM_001319850.2; = p.X595_splice on NM_032496.4) | Splice Site (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- ASB2 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- ATAD5 | c.3029G>C p.R1010T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATM | c.8005A>G p.I2669V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP4B | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ATXN2 | c.3449C>G p.S1150* (on ENST00000550104; = p.S990* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- BCAS1 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- BHMG1 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- BICRAL | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BICRAL | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BICRAL | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- BORA | c.794C>T p.S265L (on ENST00000613797; = p.S190L on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C6orf132 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D3 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- CAMK2G | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CAPZA1 | c.124_126del p.N42del | In Frame Del (DEL) | VAF 34/84 reads (40%) | called by pindel, varscan2
- CCDC178 | c.655A>C p.K219Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CDH12 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- CDH18 | c.2093C>T p.T698I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CDH23 | c.1944C>G p.N648K | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CDK12 | c.2612G>A p.G871E | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKL2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CELSR3 | c.2548G>C p.D850H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPO | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP54 | c.4495A>C p.K1499Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, varscan2
- CFTR | c.3330C>G p.F1110L | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFTR | c.3650C>G p.A1217G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CILP | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC4D | c.127C>G p.H43D | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, varscan2
- CLGN | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLTC | c.2555G>C p.R852T | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CLU | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- CSMD3 | c.9668G>A p.G3223E (on ENST00000297405 / NM_001363185.1; = p.G3054E on NM_052900.3) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD3 | c.7424C>A p.P2475H (on ENST00000297405 / NM_001363185.1; = p.P2371H on NM_052900.3) | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE1 | c.1640G>C p.S547T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DBNDD2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, varscan2
- DCAF15 | c.1303G>C p.A435P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK3 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DDX58 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGAT1 | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- DIDO1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMXL2 | c.2219G>C p.G740A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.1639G>A p.D547N (on ENST00000445597; = p.D528N on NM_001367479.1) | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH6 | c.12262G>T p.V4088L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJA4 | c.157G>A p.E53K (on ENST00000343789; = p.E82K on NM_018602.3) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- DNAJC13 | c.3265C>T p.Q1089* | Nonsense Mutation (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- DNMT3A | c.2259G>T p.W753C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAM | c.952A>C p.I318L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DSG2 | c.1821T>G p.Y607* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- DTHD1 | c.1624G>T p.E542* (on ENST00000456874; = p.E377* on NM_001136536.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | called by muse, mutect2, varscan2
- DUOXA2 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DYSF | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- EFCAB8 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- EFR3A | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ELOVL7 | c.65-1G>C p.X22_splice | Splice Site (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- EML6 | c.4347G>C p.M1449I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- ENTPD1 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC1 | c.2476C>T p.Q826* (on ENST00000360905 / NM_178040.4; = p.Q798* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVV-1 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ESS2 | c.641A>G p.E214G | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- EXT1 | c.2240G>C p.*747Sext*41 | Nonstop Mutation (SNP) | VAF 42/202 reads (21%) | called by muse, mutect2, varscan2
- FAM71C | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FANCD2 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- FANCD2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FBN3 | c.2042G>C p.R681P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by mutect2, varscan2
- FGFR2 | c.2049G>C p.Q683H | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FSD2 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYCO1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- G0S2 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRR3 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 79/220 reads (36%) | called by muse, mutect2, varscan2
- GALK1 | c.43_44insCCA p.E15delinsAK | In Frame Ins (INS) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- GALNT13 | c.1125A>C p.E375D | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBP6 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GCSAML | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GK3P | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLYR1 | c.1063A>G p.K355E | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- GNB2 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- GRIN2B | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GSC2 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HELZ | c.4740C>G p.I1580M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HEXIM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, varscan2
- ICAM5 | c.2117G>A p.G706D | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- IGFBP4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); called by muse, varscan2
- ING5 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ITCH | c.1399G>T p.E467* (on ENST00000262650 / NM_001257137.3; = p.E426* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- ITGA4 | c.2845A>G p.R949G | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD1C | c.2448G>C p.E816D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIAA1109 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA1109 | c.5360C>G p.S1787* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- KIF5A | c.2500G>C p.E834Q | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KMT2C | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPNA2P3 | n.76G>A | Splice Region (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- KPNA4 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- LIN9 | c.833C>T p.S278L (on ENST00000366808 / NM_001270410.2; = p.S223L on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LRRC37A3 | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by mutect2, varscan2
- LRRC47 | c.99_103del p.E33Dfs*149 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- LYPD2 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- MAGEB6B | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by mutect2, varscan2
- MAP1A | c.5380G>C p.E1794Q | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MAPKAP1 | c.1381C>T p.H461Y (on ENST00000265960 / NM_001006617.3; = p.H425Y on NM_024117.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MARCHF6 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MATN2 | c.2798G>C p.R933T | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MED13L | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MGAM2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSL2 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MTMR6 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC22 | c.3770C>A p.T1257K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MYH13 | c.4755dup p.E1586Rfs*23 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- MYO1E | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NBN | c.1917C>A p.N639K | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NFASC | c.2211G>T p.E737D (on ENST00000339876 / NM_001378329.1; = p.E733D on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NFATC4 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHLRC4 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NLRP10 | c.1675A>G p.R559G | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOX3 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NOX4 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- NTRK1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUFIP1 | c.352T>C p.W118R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NUP153 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NUP98 | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.625); called by muse, mutect2
- NWD2 | c.5147C>A p.P1716H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSCN | c.21254C>G p.P7085R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OR1E2 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by mutect2, varscan2
- OR52B6 | c.415T>A p.F139I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- OR9Q1 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OTOP2 | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA8 | c.2090A>T p.N697I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCLO | c.6476dup p.H2159Qfs*2 | Frame Shift Ins (INS) | VAF 27/173 reads (16%) | called by mutect2, pindel, varscan2
- PCNT | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PCYOX1 | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- PDIA6 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PIK3C2G | c.560T>C p.M187T | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAT | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PLD4 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLD5 | c.833G>C p.R278T (on ENST00000442594; = p.R216T on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PLEKHM3 | c.853C>G p.Q285E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- POLI | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLN | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- POSTN | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM6 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRPH2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PTPRO | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RABGAP1L | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, varscan2
- RALGAPA1 | c.1414G>C p.D472H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RALGPS1 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RANBP6 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RGS12 | c.3071C>T p.S1024L | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RHBDD1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RND2 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROCK1 | c.3263A>T p.E1088V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RXRB | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, varscan2
- SCN7A | c.4129C>T p.L1377F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINA4 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SETX | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 131/302 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SLC35A5 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 64/297 reads (22%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1217C>A p.T406N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLFN11 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SMARCA5 | c.2142C>G p.F714L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- SMARCD3 | c.670G>C p.V224L (on ENST00000262188 / NM_001003801.2; = p.V211L on NM_003078.4) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SNX31 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- SOX14 | c.90C>G p.N30K | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPATA31A6 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST8SIA1 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAG2 | c.971T>A p.L324H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STOX2 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- STX1B | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SUPT6H | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SUZ12 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SYNE1 | c.16502T>C p.I5501T (on ENST00000367255 / NM_182961.4; = p.I5430T on NM_033071.3) | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- TBC1D12 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBL1Y | c.815T>C p.L272S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBX18 | c.600-2A>T p.X200_splice | Splice Site (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- TFIP11 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- TLDC2 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- TLE4 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TMC1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 108/181 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TOPBP1 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TRIB2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- TSBP1 | c.1239G>C p.L413F (on ENST00000617061; = p.L418F on NM_006781.5) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC30B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TTN | c.37640T>A p.L12547H (on ENST00000591111; = p.L5123H on NM_003319.4) | Missense Mutation (SNP) | VAF 25/139 reads (18%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBA7 | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- UNC45A | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UTP20 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UTRN | c.3531G>C p.Q1177H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- VGF | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- VPS13C | c.6749G>T p.W2250L (on ENST00000644861 / NM_020821.3; = p.W2207L on NM_017684.5) | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- VPS8 | c.1292C>G p.T431R (on ENST00000625842 / NM_001349294.1; = p.T429R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- VWA3B | c.3319A>T p.K1107* | Nonsense Mutation (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- WIZ | c.3916C>A p.Q1306K (on ENST00000673675 / NM_001371589.1; = p.Q211K on NM_021241.3) | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WNK1 | c.5660C>G p.S1887C (on ENST00000315939 / NM_018979.4; = p.S1639C on NM_014823.3) | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- YARS1 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- YWHAZ | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB44 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | called by muse, varscan2
- ZKSCAN5 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZNF2 | c.1005C>G p.F335L (on ENST00000611147 / NM_001291605.2; = p.F322L on NM_021088.4) | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF430 | c.673A>T p.R225* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- ZNF626 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZNF76 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF841 | c.1339C>T p.H447Y (on ENST00000426391 / NM_001369830.1; = p.H563Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA2 | c.6912G>A p.K2304= (on ENST00000614293; = p.K2274= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- ABL2 | c.2865G>A p.G955= (on ENST00000502732 / NM_007314.4; = p.G940= on NM_005158.5) | Silent (SNP) | VAF 130/239 reads (54%) | catalogued as rs751429671; called by muse, mutect2, varscan2
- ACTL6B | c.708G>A p.K236= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV50516736; called by muse, mutect2, varscan2
- ADGRD1 | c.1833C>T p.A611= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs569143205, COSV55441792; called by muse, mutect2, varscan2
- ARHGEF28 | c.2443C>T p.L815= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs775713336; called by muse, mutect2, varscan2
- ASCC3 | c.2871T>G p.V957= | Silent (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- ASPDH | c.687G>C p.L229= (on ENST00000389208 / NM_001114598.2; = p.L124= on NM_001024656.3) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1225396714; called by muse, mutect2, varscan2
- ASTN1 | c.2970C>G p.L990= | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- BAG2 | c.363C>A p.V121= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- C2orf78 | c.2148C>G p.V716= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, varscan2
- C2orf78 | c.2382C>G p.P794= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV68519403; called by muse, mutect2
- CARNMT1 | c.207C>T p.I69= | Silent (SNP) | VAF 56/106 reads (53%) | called by muse, varscan2
- CCNF | c.939G>C p.L313= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV53543217; called by muse, mutect2
- CIT | c.1908C>G p.L636= | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- CLEC4D | c.162A>G p.G54= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as COSV100222981; called by muse, varscan2
- COL21A1 | c.372C>T p.L124= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs759882696; called by muse, mutect2, varscan2
- COL4A3 | c.771C>T p.L257= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as COSV101170525; called by muse, mutect2, varscan2
- CPT1B | c.1842C>G p.A614= | Silent (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- CPZ | c.1575C>T p.V525= (on ENST00000360986 / NM_001014447.3; = p.V514= on NM_003652.3) | Silent (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- CYP1A2 | c.495G>A p.V165= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV59659090; called by muse, mutect2, varscan2
- DDC | c.1216C>T p.L406= | Silent (SNP) | VAF 31/232 reads (13%) | catalogued as rs1399315690; called by muse, mutect2, varscan2
- DPY19L2 | c.891C>T p.L297= | Silent (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- DTNA | c.1731C>A p.I577= | Silent (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- EGR4 | c.1530C>T p.H510= (on ENST00000545030; = p.H407= on NM_001965.4) | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs377740321; called by muse, mutect2, varscan2
- EHBP1L1 | c.3333G>A p.S1111= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- ENPEP | c.579C>A p.A193= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- ERCC6L | c.492C>T p.F164= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100559263; called by muse, mutect2, varscan2
- FADS1 | c.18G>A p.A6= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- FAM172A | c.1005T>C p.I335= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as rs1396104397; called by muse, mutect2
- FGF6 | c.258G>A p.R86= | Silent (SNP) | VAF 102/215 reads (47%) | catalogued as COSV57404825; called by muse, mutect2, varscan2
- GAL3ST2 | c.552C>G p.L184= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- GDA | c.849C>G p.L283= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as COSV52994577; called by muse, mutect2, varscan2
- GDF15 | c.159C>T p.F53= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV99416159; called by muse, mutect2, varscan2
- GPR153 | c.921C>G p.L307= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as rs373529758; called by muse, mutect2, varscan2
- GPS2 | c.63C>T p.H21= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs1234176008; called by muse, mutect2, varscan2
- GTF2A1 | c.720G>T p.V240= | Silent (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- H4C3 | c.39G>A p.K13= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1261179404; called by mutect2, varscan2
- HAGHL | c.682C>T p.L228= | Silent (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- HOXD3 | c.1119C>T p.V373= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- HPSE2 | c.1035G>T p.V345= | Silent (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- HYOU1 | c.24G>A p.Q8= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV68215454; called by muse, mutect2, varscan2
- IGFBP4 | c.261G>A p.E87= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, varscan2
- INPP4B | c.2100A>G p.K700= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- KIF1A | c.2856C>T p.D952= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs761993869; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLF7 | c.585G>A p.K195= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- LMBR1L | c.1077C>T p.L359= | Silent (SNP) | VAF 61/205 reads (30%) | catalogued as rs781620146; called by muse, mutect2, varscan2
- MEN1 | c.684G>C p.L228= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV53649726; called by muse, mutect2
- MGAT3 | c.222C>T p.L74= | Silent (SNP) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- MKRN3 | c.1419G>T p.L473= | Silent (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- MNX1 | c.711C>G p.L237= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- MTO1 | c.744T>C p.I248= | Silent (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- MUC4 | c.15600G>T p.G5200= (on ENST00000463781 / NM_018406.7; = p.G964= on NM_004532.6) | Silent (SNP) | VAF 58/291 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.5658C>T p.P1886= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- MYLK | c.1029C>T p.S343= | Silent (SNP) | VAF 14/117 reads (12%) | called by mutect2, varscan2
- NEK4 | c.237C>G p.L79= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs780763463; called by muse, mutect2, varscan2
- NOTCH1 | c.7504C>T p.L2502= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- NOX3 | c.1497G>C p.V499= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- NSF | c.1881C>G p.L627= | Silent (SNP) | VAF 76/166 reads (46%) | called by muse, mutect2, varscan2
- NT5C3B | c.744C>G p.L248= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- OR4A5 | c.555A>G p.A185= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- OR5H1 | c.681A>G p.K227= | Silent (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- OR5L2 | c.357C>T p.A119= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- OR5M10 | c.9C>T p.S3= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- PAPSS1 | c.1686T>G p.V562= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- PAXIP1 | c.3171C>A p.L1057= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as COSV101249751; called by muse, mutect2
- PCDH7 | c.2136C>G p.V712= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- PMCH | c.453C>T p.L151= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, varscan2
- PPP1R16A | c.498C>G p.V166= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- PPP6R2 | c.288C>T p.L96= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as rs200665748; called by muse, mutect2, varscan2
- PSCA | c.312C>G p.L104= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- PXDN | c.1080G>A p.T360= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1475257989; called by muse, mutect2, varscan2
- SCN4A | c.4770C>G p.V1590= | Silent (SNP) | VAF 137/729 reads (19%) | called by muse, mutect2, varscan2
- SCUBE1 | c.2664C>G p.L888= | Silent (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- SF3B5 | c.150C>G p.L50= | Silent (SNP) | VAF 34/229 reads (15%) | called by muse, mutect2, varscan2
- SLC16A8 | c.489C>T p.L163= | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1674C>T p.A558= (on ENST00000377369 / NM_001145195.2; = p.A521= on NM_152725.3) | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1656C>T p.L552= | Silent (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2, varscan2
- SRRM4 | c.1774C>A p.R592= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs547801838, COSV57415107; called by mutect2, varscan2
- STEAP1 | c.324A>G p.K108= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- STON1 | c.1602G>T p.V534= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- STRC | c.4911C>G p.A1637= | Silent (SNP) | VAF 12/221 reads (5%) | called by muse, mutect2
- SUOX | c.1512G>A p.L504= | Silent (SNP) | VAF 118/313 reads (38%) | catalogued as rs1384125840; called by muse, mutect2, varscan2
- SYNGR1 | c.147C>G p.L49= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV53367623; called by muse, mutect2, varscan2
- TLR4 | c.2481G>T p.V827= (on ENST00000355622 / NM_138554.5; = p.V787= on NM_003266.4) | Silent (SNP) | VAF 98/227 reads (43%) | called by muse, mutect2, varscan2
- TSEN15 | c.210C>G p.L70= | Silent (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- UBR1 | c.132A>G p.A44= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1296605677; called by muse, mutect2, varscan2
- UCP2 | c.525C>A p.L175= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- VWA3A | c.2739G>A p.V913= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs776524437, COSV55391604, COSV55391708; called by muse, mutect2, varscan2
- WDR47 | c.873C>G p.L291= | Silent (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- ZNF140 | c.1260A>G p.K420= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- ZNF2 | c.372G>A p.L124= (on ENST00000611147 / NM_001291605.2; = p.L111= on NM_021088.4) | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- ZNF236 | c.3897C>A p.L1299= | Silent (SNP) | VAF 36/320 reads (11%) | catalogued as COSV53488714; called by muse, mutect2, varscan2
- ZNF727 | c.1251T>A p.I417= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- ZRANB1 | c.801C>T p.L267= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.54G>A p.L18= (on ENST00000252463; = p.L73= on NM_032805.3) | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs750408632; called by muse, mutect2, varscan2
- AAK1 | c.*10020C>G | 3'UTR (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- AC018638.4 | n.653C>G | RNA (SNP) | VAF 59/139 reads (42%) | called by muse, varscan2
- AC018638.4 | n.1073C>T | RNA (SNP) | VAF 79/275 reads (29%) | catalogued as rs1456601332; called by muse, mutect2, varscan2
- ACTR6 | c.379+54G>C | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- AMN | c.1258-29G>A | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs764761226; called by muse, mutect2, varscan2
- ANAPC15 | c.-113C>T | 5'UTR (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- APRT | c.*235_*242dup | 3'UTR (INS) | VAF 21/109 reads (19%) | called by mutect2, varscan2
- BTNL10 | n.371C>G | RNA (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- CCDC112 | c.1179+24C>G | Intron (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CCDC148 | c.1110+20667G>T | Intron (SNP) | VAF 36/103 reads (35%) | called by muse, varscan2
- CFAP61 | c.2503+2333G>T | Intron (SNP) | VAF 45/131 reads (34%) | catalogued as COSV55646375; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1433C>A | RNA (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- DDX39B | c.-3+244C>T | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs977223315; called by muse, mutect2, varscan2
- DNAJC19 | c.-93C>T | 5'UTR (SNP) | VAF 38/165 reads (23%) | catalogued as rs753552829; called by muse, varscan2
- DST | c.4296+4539C>T | Intron (SNP) | VAF 11/59 reads (19%) | catalogued as rs1479506135; called by muse, mutect2, varscan2
- EIF3L | c.82+496G>C | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- EVX1 | chr7:27239352 C>G | 5'Flank (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- FAM135B | c.157+1841C>A | Intron (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- FAM161B | c.-70C>G | 5'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- FOLH1 | c.119-685A>T | Intron (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- GPRC5C | c.1187-84A>G | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- HAX1 | c.*20C>G | 3'UTR (SNP) | VAF 43/108 reads (40%) | catalogued as rs769582304; called by muse, mutect2, varscan2
- HMGA2 | c.198+21C>T | Intron (SNP) | VAF 104/254 reads (41%) | called by muse, mutect2, varscan2
- JMJD8 | c.176+27C>T | Intron (SNP) | VAF 47/113 reads (42%) | catalogued as rs754351687; called by muse, mutect2, varscan2
- KRT17P1 | n.1108C>T | RNA (SNP) | VAF 37/174 reads (21%) | catalogued as rs1454736472; called by muse, mutect2, varscan2
- LHX3 | c.79+1945C>A | Intron (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- LINC00115 | n.379C>T | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- LINC02649 | n.364A>T | RNA (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11072G>T | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, varscan2
- MACF1 | c.543+11149G>A | Intron (SNP) | VAF 29/110 reads (26%) | called by muse, varscan2
- MAGEC3 | c.910-517G>A | Intron (SNP) | VAF 23/45 reads (51%) | catalogued as rs977303461, COSV68924151; called by muse, mutect2, varscan2
- MASP1 | c.1304-4484G>C | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- MGAT5B | c.1025+7602G>A | Intron (SNP) | VAF 25/140 reads (18%) | called by muse, mutect2, varscan2
- MLX | c.*1256G>T | 3'UTR (SNP) | VAF 78/175 reads (45%) | called by muse, mutect2, varscan2
- MOGS | c.580-26C>G | Intron (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- MRPS5 | c.763+28G>T | Intron (SNP) | VAF 81/295 reads (27%) | called by muse, mutect2, varscan2
- MUTYH | c.568-20G>C | Intron (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- MYH16 | n.2710G>C | RNA (SNP) | VAF 16/113 reads (14%) | catalogued as rs1239166418; called by muse, mutect2, varscan2
- NCR2 | c.644+832G>A | Intron (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- NDUFAF7 | c.*6C>G | 3'UTR (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604414 A>T | 5'Flank (SNP) | VAF 13/99 reads (13%) | catalogued as rs1337211722; called by muse, mutect2, varscan2
- PLEKHH2 | c.186+597A>G | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- POM121L4P | n.1344G>A | RNA (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- PRR34 | n.326G>C | RNA (SNP) | VAF 8/34 reads (24%) | catalogued as rs768072686, COSV61549124, COSV61549256; called by muse, varscan2
- PSMD1 | c.-24G>C | 5'UTR (SNP) | VAF 34/102 reads (33%) | catalogued as rs751789853; called by muse, mutect2, varscan2
- PTAR1 | c.983-23G>A | Intron (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- RALYL | c.257-68576G>T | Intron (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- RELL1 | c.*3+8550C>G | Intron (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- RHOA | c.409-600C>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1252024049; called by mutect2, varscan2
- RIMS2 | c.2197-3406A>G | Intron (SNP) | VAF 37/384 reads (10%) | called by muse, mutect2, varscan2
- SEC22C | c.*4648C>G | 3'UTR (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- SEMA3C | chr7:80922301 C>T | 5'Flank (SNP) | VAF 12/95 reads (13%) | catalogued as rs772871598; called by muse, mutect2, varscan2
- STX1A | c.540+368G>C | Intron (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- THUMPD2 | c.673-523G>T | Intron (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.543-28A>G | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, varscan2
- TP53BP1 | chr15:43406628 G>C | 3'Flank (SNP) | VAF 17/200 reads (9%) | called by muse, mutect2
- TPM3 | c.775+13G>C | Intron (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222392 del T | 5'Flank (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- TRIM56 | c.*2063T>C | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as rs1443420903; called by mutect2, varscan2
- TRIM74 | chr7:72969913 G>A | 5'Flank (SNP) | VAF 49/150 reads (33%) | catalogued as rs782236939; called by muse, mutect2, varscan2
- URM1 | c.*11C>G | 3'UTR (SNP) | VAF 56/102 reads (55%) | catalogued as COSV65717107; called by muse, mutect2, varscan2
